Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IG, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IG-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

(B) BILATERAL PELVIC LYMPH NODES:
Nineteen benign lymph nodes(0/19).

Entire report and diagnosis completed by

CSCE ICD-O-3
Adenocarcinoma acinar
path 8/40/13
Adenocarcinoma NOS
Site Prostate NOS 8/40/13
C61.9
JW 11/24/13

GROSS DESCRIPTION

(A) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

(B) BILATERAL PELVIC LYMPH NODES - Two unoriented, irregular pieces of adipose tissue (aggregate measurement 6.0 x 3.5 x 2.0 cm). Nineteen possible unremarkable lymph nodes are identified (sizes range from 0.2 to 2.5 cm).

SECTION CODE: B1, five possible lymph nodes; B2, three possible lymph nodes; B3, two possible lymph nodes; B4, two possible lymph nodes; B5, two possible lymph nodes; B6, one possible lymph node; B7, one possible lymph node, bisected; B8, one possible lymph node, bisected; B9, one possible lymph node, bisected; B10, one possible lymph node, bisected.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

T-92000, T-C4600, M-Y1973

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(A) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4 + 3) WITH TERTIARY GLEASON GRADE 5. (SEE COMMENT.).

TUMOR EXTENDING FOCALLY INTO EXTRAPROSTATIC TISSUE.

TUMOR EXTENDING TO THE MARGIN OF RESECTION.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

COMMENT

The prostate gland contains three foci of prostatic adenocarcinoma, one in the transition zone and two in the peripheral zone. The dominant tumor focus and the one of the highest histologic grade is located in the right and left transition zone. This tumor focus measures 3.0 x 1.5 cm in the largest cross-sectional dimension, and it is present in four cross sections and extensively in the apical region. This tumor focus exhibits predominately Gleason grades 4 and 3. A minor (tertiary) component of Gleason grade 5 is also present. This tumor exhibits focal extraprostatic extension (less than 1.0 mm) in the right anterior surface of the prostate and extends to the margin of resection in the anterior apical region. The extent of marginal involvement is 6.0 mm. The two peripheral zone foci are located in the left posterolateral and right lateral peripheral zone. The tumor located in the left posterolateral peripheral zone measures 0.8 x 0.4 cm in the largest cross-sectional dimension, and it is present in the first cross section of the prostate. The third tumor focus is located in the right lateral peripheral zone. This tumor measures 0.5 x 0.2 cm in the largest cross-sectional dimension, and it is present in one cross section. The non-dominant tumor foci are of lower histologic grade (Gleason score 6/3 + 3) and are confined to the prostate with negative margins.

GROSS DESCRIPTION

(A) PROSTATE AND SEMINAL VESICLES - A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (2.5 x 2.2 x 4.0 cm, 31 grams, post fixation) has the usual shape. The soft tissue present along the right and left posterolateral aspects of the prostate appears symmetrical. A palpable and visible nodule is observed in the left mid region of the prostate. Serial cross sections after fixation demonstrate firm areas consistent with tumor in the right transition zone and right peripheral zone of the first three of the four cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: A1, A2, base of right seminal vesicle and right vas deferens; A3, A4, base of left seminal vesicle and left vas deferens; A5, prostatic base, right border; A6, A7, prostatic base, right posterior border; A8, A9, prostatic base, central portion; A10, prostatic base, left border; A11, A12, prostatic base, left posterior border; A13, A14, apex anterior; A15, apex left;

[page 3 of 3]
Specimen Date/Time:

A16-A18, apex posterior; A19, apex right; A20-A35, sections of the four cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black.

SNOMED CODES

T-92000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria	lv 10/23/13	Yes	No

Source: NCI Genomic Data Commons file a9fe60c5-6414-4589-8ed8-1a69df77ca41 (TCGA-KK-A8IG.D1F786EC-03F5-458B-99AC-3B89EFFF2297.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).